Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3FP, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3FP-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Parathyroid: Right upper parathyroid QS
2. Parathyroid: Right inferior parathyroid/qs
3. Thyroid: Subtotal thyroid stitch marks upper pole right lobe

ICD-0-3

carcinoma, papillary, follicular
variant 8340/3

Site: thyroid, NOS C73.9 lw 11/22/11

Diagnosis

1. No pathological diagnosis: Parathyroid (right upper) biopsy
2. No pathological diagnosis: Parathyroid (right inferior) biopsy
3. Multifocal papillary carcinoma, dominant follicular variant, 2.2 cm, right; mild follicular nodular disease and chronic lymphocytic thyroiditis: Thyroid
No pathological diagnosis: Lymph nodes, 2, right perithyroidal
No pathological diagnosis: Lymph node, 1, isthmus
- Right hemithyroidectomy specimen

Synoptic Data

Procedure: Right hemithyroidectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Right lobe:
4.0 cm
3.8 cm
1.5 cm
Isthmus +/- pyramidal lobe:
4.5 cm
1.9 cm
1.0 cm
Specimen Weight: 19.3 g
Tumor Focality: Multifocal, ipsilateral
Multifocal, midline (isthmus)
----- DOMINANT TUMOR -----
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 2.2cm
Additional dimension: 1.7 cm
Additional dimension: 1.6 cm
Histologic Type: Papillary carcinoma, follicular variant

Reviewed (Initials)	KMH lw 11/22/11 V12/11	

[page 2 of 3]
Surgical Pathology Consultation Report

Histologic Grade:	Follicular architecture
Margins:	Classical cytomorphology
Tumor Capsule:	Not applicable
Tumor Capsular Invasion:	Margins uninvolved by carcinoma
Lymph-Vascular Invasion:	Partially encapsulated
Perineural Invasion:	Present, extent minimal
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Isthmus
Tumor Size:	Greatest dimension: 0.4cm
Histologic Type:	Papillary carcinoma, follicular variant
	Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
	Papillary carcinoma, oncocytic or oxyphilic variant
	Follicular architecture
	Classical cytomorphology
	Oncocytic or oxyphilic cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis
	Number of regional lymph nodes examined: 3
	Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease
	Thyroiditis
	Parathyroid gland(s), within normal limits
	Other: additional 0.05 cm oncocytic follicular variant papillary microcarcinoma, right lobe

*Pathologic Staging is based on AJCC/UICC TNM

Electronically verified by:

Gross Description

1. The specimen labeled with the patient's name as "RT upper parathyroid QS" and consists of a fragment of tissue that measures 0.2 x 0.2 x 0.1 cm. The specimen is submitted in toto for frozen section.

1A resubmitted frozen tissue

2. The specimen labeled with the patient's name as "RT inferior parathyroid QS" and consists of a fragment of tissue that measures 0.2 x 0.2 x 0.1 cm. The specimen is submitted in toto for frozen section.

2A resubmitted frozen tissue

3. The specimen labeled with the patient's name and as "Subtotal thyroid stitch marks upper pole RT lobe" consists of a right hemithyroidectomy specimen that is received oriented with a suture and weighs 19.3 g. The right lobe measures 4.0 cm SI x 3.8 cm ML x 1.5 cm AP and the isthmus measures 4.5 cm SI x 1.9 cm ML x 1.0 cm AP. The external surfaces

[page 3 of 3]
Surgical Pathology Consultation Report

have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or no lymph nodes are identified grossly. The right lobe contains 1 delineated, fleshy, yellow-pink nodule that measures 2.2 cm SI x 1.6 cm ML x 1.7 cm AP. The remainder of the thyroid tissue is red-brown with several other poorly defined nodules many of which have a translucent red appearance. Sections of the nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

3A-J right lobe, superior to inferior (nodule in C-I)

3K-M isthmus

Quick Section Diagnosis

1A (right upper parathyroid) – parathyroid tissue present
Reported to OR13 a

2A (right inferior parathyroid) – parathyroid tissue present
Reported to OR13 at

Source: NCI Genomic Data Commons file c87ef506-3a67-4330-a253-949687758e1f (TCGA-EM-A3FP.59293B22-6D8E-4DC9-ABED-B4831E4FB34B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).